Somatic mutation profile of tumor specimen C3L-07488-54 (aliquot CPT0452520002) from CPTAC case C3L-07488, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 64.5 years (23,562 days).
Specimen C3L-07488-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9c40c25-a8a8-4387-ac0e-0b68634fd1ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07488-50 (Buccal Cell Normal), aliquot CPT0452480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03bc427a-321b-43bf-bdf4-2064133fbc18

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 2, Splice Region 1, 3'UTR 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A2 | c.1401G>A p.P467= | Splice Region (SNP) | VAF 46/603 reads (8%) | catalogued as rs1553515794, CS129068; ClinVar: likely pathogenic; called by muse, mutect2
- KIAA0753 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs919816098, COSV100810514; called by muse, varscan2
- LRRIQ1 | c.2035G>C p.G679R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV67825055; called by muse, mutect2, varscan2
- LYAR | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs139524971; called by muse, varscan2
- NCALD | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 142/324 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1212404446, COSV99637596; called by muse, mutect2, varscan2
- SVEP1 | c.5378G>A p.G1793E | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs749945364, COSV52836896; called by muse, mutect2, varscan2
- TET2 | c.4303C>T p.Q1435* | Nonsense Mutation (SNP) | VAF 101/244 reads (41%) | catalogued as COSV54412254; called by muse, mutect2, varscan2
- ADAMTS4 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 147/324 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 71/700 reads (10%) | called by muse, mutect2, varscan2
- HOMEZ | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RILPL1 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 156/432 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPI1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 177/603 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SSTR4 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- TNPO2 | c.2567T>A p.L856H (on ENST00000425528 / NM_001382240.1; = p.L846H on NM_013433.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/301 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH15 | c.699G>A p.A233= | Silent (SNP) | VAF 270/634 reads (43%) | catalogued as rs765916491; called by muse, mutect2, varscan2
- EIF3L | c.276G>A p.Q92= | Silent (SNP) | VAF 39/371 reads (11%) | catalogued as COSV66045660; called by muse, mutect2, varscan2
- MKNK2 | c.1068G>A p.R356= | Silent (SNP) | VAF 164/406 reads (40%) | catalogued as rs770042483, COSV51734917; called by muse, mutect2, varscan2
- OSCAR | c.795G>A p.Q265= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2
- TMEM132C | c.499C>T p.L167= | Silent (SNP) | VAF 177/508 reads (35%) | catalogued as rs375513600; called by muse, mutect2
- ZPBP | c.162C>T p.R54= | Silent (SNP) | VAF 19/190 reads (10%) | called by muse, mutect2
- AC020907.6 | c.-461A>G | 5'UTR (SNP) | VAF 236/564 reads (42%) | called by muse, mutect2, varscan2
- PLEKHJ1 | c.94+62G>A | Intron (SNP) | VAF 18/170 reads (11%) | catalogued as rs557308290; called by muse, mutect2, varscan2
- UCP2 | c.*32G>A | 3'UTR (SNP) | VAF 61/751 reads (8%) | called by muse, mutect2
